Surgical pathology report (de-identified scan), TCGA case TCGA-FG-5963, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-5963-02A (Recurrent Tumor).

SURGICAL PATHOLOGY REPORT

Race:

CAUCASIAN

DOB/Sex:

/ M

FINAL DIAGNOSIS

A. LEFT FRONTAL TUMOR, EXCISION:

--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

B. DEEP WHITE MATTER, BIOPSY:

--HYPERCELLULAR GRAY AND WHITE MATTER, NO SOLID TUMOR IDENTIFIED.

C. TUMOR, EXCISION:

--GLIOBLASTOMA MULTIFORME (WHO GRADE IV), SEE NOTE.

Note: There is

Electronically Signed Out By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Microscopic diagnosis: Malignant glioma.

Clinical History:

Left frontal cerebral lesion

Specimens Submitted As:

A:LEFT FRONTAL TUMOR

B:DEEP WHITE MATTER

C:TUMOR

1CD-0-3

glioblastoma multiforme 9440/3

Site: brain, frontal lobe C71.1

ju
10/23/12

Gross Description:

A. Received fresh for intraoperative consultation, labeled with the patient's name, Hospital number, and "left frontal tumor," is a 0.4 x 0.3 x 0.1 cm tan-red soft tissue specimen. A frozen section is performed on the entire specimen. The specimen is submitted entirely in one cassette.

~~B: Received fresh, labeled with the patient's name and number, and "A-deep white matter", is one irregular, opaque white to pink-tan, soft tissue fragment measuring 0.7 x 0.4 x 0.2 cm. Submitted in toto in one cassette.~~

C: Received fresh, labeled with the patient's name and number, and "B", are multiple irregular, opaque white to pink tan to brown, soft tissue fragments measuring in aggregate 1.4 x 1.1 x 0.25-cm. Submitted in toto in one cassette.

(LGG progressed to GBM recurrence)

Recurrence

Diagnostic Discrepancy		
HPA Discrepancy		
Pathologic Malignancy History		
Case 1: (circle):		

Source: NCI Genomic Data Commons file 55a041d5-080f-4248-8fa3-a1413ce457be (TCGA-FG-5963.6BDCE0AC-CDC9-45A2-B796-7A06284251FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).